Surgical pathology report (de-identified scan), TCGA case TCGA-06-0877, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0877-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

06-0877

CLINICAL HISTORY

[REDACTED] has a heterogeneously enhancing mass within the medial left temporal lobe, with extension to thalamic and subthalamic and ventricular subependymal regions.

OPERATIVE DIAGNOSES

Basal ganglia lesion.

Operation/Specimen: A: Left temporal

B: Left temporal

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left temporal lobe, biopsy and excision:

1. Glioblastoma.
2. MIB-1 proliferation index: 5%.
- See Comment.

COMMENT

The lesion is an astrocytic neoplastic proliferation with nuclear anaplasia, mitotic activity, microvascular cellular proliferation and necrosis, and tumor necrosis, occasionally with pseudopalisading, i.e. a glioblastoma. The neoplasm infiltrates the cerebrum diffusely, and is focally present on the surface of cerebral tissue. In the tissues examined, the mitotic rate is low and the proliferation index is not very high.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

[page 2 of 3]
Testing performed on tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Left temporal, touch prep and smears: Glioma, high histological grade. Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

Received fresh, four fragments, 1.3 cm. in aggregate. Semi firm, hemorrhagic, and focally glistening. In total, A1 and A2.

B.

SPECIMEN: Left temporal tumor.

FIXATIVE: Formalin.

GENERAL: A 3.0 x 2.5 x 1.0 cm., 2.88 gm. aggregate of two pieces of pale red-tan to gray-tan brain tissue. Fragments are sectioned.

SECTIONS: B1-B4 all submitted.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The neoplastic cells are gliofibrillogenic. Only a very small minority of neoplastic cells over expresses the p53 protein. The NeuN and synaptophysin demonstrate the neoplastic cells infiltrating grey and white matter. The neurofilament is negative. There are no apparent neuronal neoplastic elements. With the MIB-1 there is a proliferation index of about 5% in the more active areas.

ICD-9(s):

239.6 239.6

[REDACTED]

[page 3 of 3]
Histo Data

Part A: Left temporal

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
NeuN x 1	1	[REDACTED]	
NF2F11 x 1	1	[REDACTED]	
P53DO7 x 1	1	[REDACTED]	
Synap-DA x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
Rct 1 H/E x 1	2	[REDACTED]	
Rct 2 H/E x 1	2	[REDACTED]	

Part B: Left temporal

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
H/E x 1	4	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 7d308e76-1ce0-486a-82ea-e505bf6ce544 (TCGA-06-0877.CE4F12D9-D24E-41A8-9841-075D30530173.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).